CPTAC case C3L-05907 — Hematopoietic and reticuloendothelial systems — Myeloid Leukemias (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Myeloid Leukemias; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/f0729adc-bb57-4bf6-9fc4-94ad10f8606f

Demographics
Sex at birth: male; Race: white; Year of birth: 1972; Vital status: Dead; Days to death: 659 days (1.8 years); Year of death: 2021; Cause of death: Not Cancer Related; Country of birth: Russia.

Diagnoses (1)
1. Acute myeloid leukemia, NOS: ICD-O-3 morphology code: 9861/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Bone marrow; Age at diagnosis: 46.9 years (17,119 days); Year of diagnosis: 2019; Days to last known disease status: 659 days (1.8 years); Progression or recurrence: yes; Days to recurrence: 331 days; Days to last follow up: 739 days (2.0 years).
   Chemotherapy — whether it was given is not recorded by GDC; Treatment outcome: Complete Response.

Follow-up (2 entries)
- Days to follow up: 457 days (1.3 years); Karnofsky performance status: 70; ECOG performance status: 2.
- Days to follow up: 739 days (2.0 years); Progression or recurrence: Yes; Days to recurrence: 331 days; Karnofsky performance status: 0; ECOG performance status: 5.

Other clinical attributes
- Weight: 86.5 kg; Height: 178 cm; BMI: 27.3.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (5 samples)
- Samples C3L-05907-51, C3L-05907-52, C3L-05907-53 (3 with the same recorded description): Sample type: Buccal Cell Normal; Tissue type: Normal; Specimen type: Buccal Cells; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC).
- Samples C3L-05907-54, C3L-05907-55 (2 with the same recorded description): Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Frozen; Freezing method: -80 (unit not recorded by GDC); Days to sample procurement: 1 day; Time between excision and freezing: 285 minutes; Method of sample procurement: Bone Marrow Aspirate; Diagnosis pathologically confirmed: Yes.
